Surgical pathology report (de-identified scan), TCGA case TCGA-FW-A3TV, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site International Genomics Consortium, specimen TCGA-FW-A3TV-06A (Metastatic).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

None:

Final Report

DIAGNOSIS

A) SKIN OF BACK, WIDE LOCAL EXCISION:

1. Scar consistent with previous biopsy/excision site - see comment
2. No evidence of residual or recurrent melanoma
3. The scar is free of all margins (2.6 cm from 3 o'clock, 2.8 cm from 9 o'clock, 1.1 cm from 12 o'clock and 1 cm from 6 o'clock peripheral margins)

B) LEFT AXILLARY LYMPH NODE, SENTINEL #1, EXCISION: One benign lymph node by routine and immunohistochemical stains (0/1) - see comment

C) LEFT AXILLARY LYMPH NODE, SENTINEL #2, EXCISION: One benign lymph node by routine and immunohistochemical stains (0/1) - see comment

D) LYMPH NODES, RIGHT AXILLARY CONTENTS, RIGHT AXILLARY DISSECTION:

Metastatic melanoma in one of twenty five lymph nodes (1/25) characterized by:

- a. Metastatic focus: 2 cm
- b. Extracapsular extension: Present

COMMENT

B-C) The evaluation of the sentinel node specimens, including histologic evaluation of H&E levels, and immunohistochemical stains (using antibodies to Melan A and melanoma cocktail composed of MART-1 and Tyrosinase antibodies) was performed in accordance with the standard departmental procedure and has been approved by medical staff committees. The stains were performed on blocks B1, B2, C1 and C2.

D) There is no residual melanoma present within this wide local excision, presumably the patient had a previous biopsy, however, no prior pathology material is present within our system. If the prior material was made available to us we would review it and incorporate it into complete staging parameters as clinically desired.

Attending Pathologist:

CLINICAL INFORMATION

Per Dr. procedure and discharge summary notes, the patient undergoes wide local excision of a melanoma of the back and left axillary sentinel lymph node dissection. No prior pathology specimens are present within our network, and no note is made within the EMR with specifics of the melanoma history. The patient is status post right axillary lymph node FNA which was positive for metastatic melanoma.

1CD-0-3
melanoma, NOS
872013
Site: lymph node, axillary
4-3-12 C77.3
RD

[page 2 of 3]
[REDACTED]

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Melanoma, stitch marks superior wide local excision of back. Labeled "wide local excision of back, stitch marks superior" is a 7 x 3.2 cm ellipse of tan skin, excised to 1.8 cm with black suture secured to the mid aspect of one edge denoting superior (redesignated 12 o'clock). The central tan skin discloses a 1.1 x 1.1 cm gray-brown thickened, plaque-like scar, 2.6 cm from the 3 o'clock tip, 2.8 cm from the 9 o'clock tip, 1.1 cm from the 12 o'clock margin and 1 cm from the 6 o'clock margin. The 12-3 o'clock margin is inked blue, 3-6 o'clock margin inked green, 6-9 o'clock margin inked red, 9-12 o'clock margin inked yellow and the central deep soft tissue margin is inked black. The specimen is serially sectioned disclosing focal hemorrhage deep to the aforementioned scar, without discrete masses or hyperpigmentation.

Representative sections including entire central lesion and nearest margins are submitted in 19 cassettes as follows:

1. 3 and 9 o'clock tips
- 2-3. Central, composite slice 1
- 4-5. Central, composite slice 2
- 6-7. Central, composite slice 3
- 8-9. Central, composite slice 4
- 10-11. Central, composite slice 5
- 12-13. Central, composite slice 6
- 14-15. Central, composite slice 7
- 16-17. Central, composite slice 8
- 18-19. Central, composite slice 9

NOTE: Composites slices are submitted sequentially from 3 o'clock to 9 o'clock. Composite slices 4-6 include entire skin lesion and nearest margins.

Note: Specimen removed from patient at [REDACTED] specimen placed in 10% neutral buffered formalin at [REDACTED]. Specimen fixed in formalin for a minimum of 6 hours, and not longer than 48 hours.

[REDACTED]

B) SOURCE: Sentinel node #1, melanoma, left axillary
The specimen is received labeled "left axillary sentinel node #1." It consists of a 1.5 cm rubbery tan fatty lymph node, sectioned disclosing no discrete lesions or hyperpigmentation. Entirely submitted in two cassettes.

C) SOURCE: Sentinel node #2, melanoma, left axillary
The specimen is received labeled "left axillary sentinel node #2." It consists of a 1.3 cm rubbery tan partially fatty lymph node, sectioned disclosing no discrete lesions or hyperpigmentation. Entirely submitted in two cassettes.

[REDACTED]

D) SOURCE: Axillary contents, right
Received fresh labeled "right axillary contents" consists of an unoriented lobulated portion of adipose and fibrous tissue measuring 12 x 11 x 4 cm. Within this tissue are 26 mottled tan fatty lymph nodes ranging from 0.1-3.1 cm in greatest dimension.

NOTE: Tissue is taken for possible ancillary studies.

Nodes are entirely submitted in 19 cassettes as follows:

1. Four nodes
- [REDACTED]

[page 3 of 3]
- [REDACTED]
- 2-6. Second largest node, sectioned
7. Five nodes
8. Five nodes
9. Three nodes
10. Two nodes, one bisected, inked blue
11. One node, bisected
- 12-13. One node, bisected
14. One node, bisected
15. One node, bisected
16. One node, bisected
- 17-19. Largest node, sectioned

This case is accessioned in

Gross dictation by: [REDACTED]

MICROSCOPIC

The microscopic appearance substantiates the diagnosis.

Dictation by: [REDACTED] transcribed by [REDACTED]

Interpreted at

COLLECTED: ACCESSIONED: SIGNED:

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL
Information

in

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL
Report

Order Result History

Lab Status

Order Complete [3]

on

Result Information

Result Date and Time

Status

Provider Status

Final result

Ordered

Lab Information

Lab

As

Order Details

Parent Order ID

Entry Date

Specimen Information

Specimen Source

Collection Date

Collection Time

Other

Source: NCI Genomic Data Commons file 73f5578a-48be-4e2f-9a94-ba5cdececd60 (TCGA-FW-A3TV.5F24E2F6-D00F-4F0E-B640-B4688AA97B86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).